Somatic mutation profile of tumor specimen TCGA-58-A46K-01A (aliquot TCGA-58-A46K-01A-11D-A24D-08) from TCGA case TCGA-58-A46K, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.9 years (21,867 days).
Specimen TCGA-58-A46K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 065e42ee-8299-4b4a-a9a0-1bf646952c15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-58-A46K-10A (Blood Derived Normal), aliquot TCGA-58-A46K-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e726d8f-490b-4352-a3bf-a3bfe063dabe

The open-access MAF lists 137 somatic variants for this specimen: 94 protein-altering or splice-affecting, 37 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 37, Nonsense Mutation 7, Splice Site 3, 3'UTR 2, RNA 2, Intron 1, Frame Shift Del 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 48/84 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.1063T>C p.Y355H | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100750599, COSV100751262; called by muse, mutect2, varscan2
- ALK | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs149145987; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMER2 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs559701365, COSV63440759; called by muse, mutect2, varscan2
- ANKFY1 | c.2237G>T p.R746L (on ENST00000341657 / NM_001330063.2; = p.R747L on NM_016376.5) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58918602, COSV58920120; called by muse, mutect2, varscan2
- APOB | c.5425A>T p.T1809S | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.43); catalogued as COSV99268744; called by muse, mutect2, varscan2
- ARHGAP32 | c.1674C>A p.F558L (on ENST00000310343 / NM_001378025.1; = p.F209L on NM_014715.4) | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV100089786; called by muse, mutect2, varscan2
- ARHGEF18 | c.1565A>T p.Y522F (on ENST00000359920 / NM_001130955.2; = p.Y418F on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100150174; called by muse, mutect2, varscan2
- C12orf42 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.319); catalogued as COSV59391129; called by muse, mutect2, varscan2
- C3orf33 | c.158T>G p.L53W (on ENST00000340171 / NM_001308229.2; = p.L10W on NM_173657.2) | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.792); catalogued as COSV100420197; called by muse, mutect2
- CACNA1G | c.6703G>C p.E2235Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.081); catalogued as COSV100662757; called by muse, mutect2, varscan2
- CHURC1 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as COSV100767510; called by muse, mutect2
- CLEC4E | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV100222784; called by muse, mutect2, varscan2
- COL6A6 | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1399930209, COSV100651115; called by muse, mutect2
- CREB3 | c.893C>A p.S298* | Nonsense Mutation (SNP) | VAF 66/124 reads (53%) | catalogued as COSV100148390; called by muse, varscan2
- CSE1L | c.1133-1G>A p.X378_splice | Splice Site (SNP) | VAF 18/77 reads (23%) | catalogued as COSV99522266, COSV99522338; called by muse, mutect2, varscan2
- CTNNA2 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV100786739; called by muse, mutect2
- DDX3Y | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.58); catalogued as COSV100267621; called by muse, mutect2, varscan2
- ERICH3 | c.3043G>A p.E1015K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs1243857656, COSV58600105; called by muse, mutect2, varscan2
- FBXL6 | c.1550G>T p.R517L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57351359; called by muse, mutect2, varscan2
- FUT9 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs188064752, COSV100134701; called by muse, mutect2, varscan2
- GAPVD1 | c.2852C>G p.P951R (on ENST00000394104; = p.P978R on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99782584; called by mutect2, varscan2
- GRK5 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV100963142, COSV100963345; called by muse, mutect2, varscan2
- HELZ | c.2964C>G p.F988L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100699141; called by muse, mutect2, varscan2
- HGF | c.1774G>C p.D592H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV55959834, COSV99738925; called by muse, mutect2, varscan2
- IDH3G | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as COSV99473501; called by muse, mutect2, varscan2
- KANK1 | c.3554-1G>A p.X1185_splice | Splice Site (SNP) | VAF 32/68 reads (47%) | catalogued as COSV101207004; called by muse, mutect2, varscan2
- KCNH5 | c.2008C>G p.L670V | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV100528551; called by muse, mutect2
- KIF1A | c.1894A>G p.I632V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1208366245, COSV100242764; called by muse, mutect2, varscan2
- KNL1 | c.2262G>C p.Q754H (on ENST00000346991 / NM_170589.5; = p.Q728H on NM_144508.5) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100707193; called by muse, mutect2, varscan2
- LAMB3 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV100620581; called by muse, mutect2, varscan2
- LDB2 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100455240; called by muse, mutect2, varscan2
- LRRC4C | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV53417350, COSV99536828; called by muse, mutect2, varscan2
- MB21D2 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1273131293, COSV66663834; called by mutect2, varscan2
- MGAM | c.604G>C p.V202L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs368879552, COSV101516582; called by muse, mutect2, varscan2
- MORC1 | c.2474T>A p.L825* | Nonsense Mutation (SNP) | VAF 38/130 reads (29%) | catalogued as COSV99228228; called by muse, mutect2, varscan2
- MRFAP1L1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs376876657; called by muse, mutect2, varscan2
- MUC5AC | c.15332C>T p.T5111M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs764079341, COSV100611265; called by muse, varscan2
- MUC5B | c.7283C>G p.S2428C | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV101500967; called by muse, mutect2, varscan2
- MYH2 | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs1465976033, COSV99821224; called by muse, mutect2
- NAALAD2 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV100428954; called by muse, mutect2, varscan2
- NAGA | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV101124183, COSV67170272; called by muse, mutect2, varscan2
- NFKBIZ | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs749786505, COSV100396892, COSV58202035; called by muse, mutect2, varscan2
- NOL11 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99475343; called by muse, mutect2, varscan2
- NR3C2 | c.1157A>C p.N386T | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV100679976; called by muse, mutect2, varscan2
- NRDE2 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs983526409, COSV100583742, COSV62962330; called by muse, mutect2
- NTNG2 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62368769; called by muse, mutect2, varscan2
- OR2G3 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100180841; called by muse, mutect2
- OR2L13 | c.405G>C p.M135I | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs1322978288, COSV100813920, COSV63554288; called by muse, mutect2
- OR2M3 | c.336C>G p.C112W | Missense Mutation (SNP) | VAF 22/381 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV101513550, COSV71758927, COSV71759031; called by muse, mutect2
- OR2M3 | c.578C>A p.S193* | Nonsense Mutation (SNP) | VAF 101/349 reads (29%) | catalogued as COSV101513552; called by muse, mutect2, varscan2
- OR4F6 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as rs756348133, COSV61026852; called by muse, mutect2, varscan2
- OR8D2 | c.491C>G p.S164* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100659147; called by muse, mutect2, varscan2
- PCDHB11 | c.2038C>G p.Q680E | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV100697221; called by muse, mutect2
- PCDHB7 | c.1403T>C p.L468P | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99177610; called by muse, mutect2, varscan2
- PHLDB2 | c.2983A>T p.S995C (on ENST00000393925 / NM_001134439.2; = p.S952C on NM_145753.2) | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV101208800; called by muse, mutect2, varscan2
- PKD1L1 | c.4535G>A p.S1512N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99221789; called by muse, mutect2, varscan2
- POLD4 | c.297C>T p.C99= | Splice Region (SNP) | VAF 17/56 reads (30%) | catalogued as COSV56745149; called by muse, mutect2, varscan2
- PPARD | c.214A>G p.M72V | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs763849875, COSV100283448; called by muse, mutect2, varscan2
- PPP1R3A | c.3140A>C p.D1047A | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99494787; called by muse, mutect2, varscan2
- PREB | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.38); catalogued as COSV53208119, COSV99574901; called by muse, mutect2, varscan2
- PSMA3 | c.12C>G p.I4M | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV99373575; called by muse, mutect2
- QSER1 | c.3903T>A p.Y1301* (on ENST00000399302; = p.Y1430* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101235000; called by muse, mutect2
- RASIP1 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99711198; called by muse, mutect2, varscan2
- RCE1 | c.914C>G p.P305R | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100547209; called by muse, mutect2
- SLC17A7 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV99677141; called by muse, mutect2
- SLC17A8 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100035958; called by muse, mutect2, varscan2
- SNRNP200 | c.5043C>G p.I1681M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.589); catalogued as COSV100108192; called by muse, mutect2, varscan2
- SPRTN | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV50478281; called by muse, mutect2, varscan2
- TAF1 | c.4408C>T p.R1470C (on ENST00000373790 / NM_138923.4; = p.R1491C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99337423; called by muse, mutect2
- TBXAS1 | c.1316A>G p.H439R | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99696244; called by muse, mutect2, varscan2
- TCP1 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV100365128; called by muse, mutect2, varscan2
- TEAD1 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV100533067; called by muse, mutect2, varscan2
- TMC3 | c.1268T>C p.I423T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs555461104, COSV100846081; called by muse, mutect2, varscan2
- TMCC2 | c.1098G>C p.Q366H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.984); catalogued as COSV100319604; called by muse, mutect2, varscan2
- TMCC2 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100319607; called by muse, mutect2, varscan2
- TNRC6B | c.491A>G p.Y164C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1400821467, COSV100110755; called by muse, mutect2, varscan2
- TRIM48 | c.634G>C p.G212R | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.868); catalogued as COSV101338384; called by muse, mutect2
- TRMO | c.285G>C p.L95F | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100796017; called by muse, mutect2, varscan2
- TTN | c.45634C>A p.P15212T (on ENST00000591111; = p.P7788T on NM_003319.4) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | PolyPhen probably damaging (0.999); catalogued as COSV100635884; called by muse, mutect2, varscan2
- TXNDC16 | c.1085A>G p.N362S | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1566555398, COSV99909798; called by muse, mutect2, varscan2
- USH1C | c.1353G>T p.K451N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV99142532; called by muse, mutect2, varscan2
- USP3 | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.089); catalogued as COSV99165837; called by muse, mutect2, varscan2
- USP42 | c.1486G>C p.V496L | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV100085036; called by muse, mutect2, varscan2
- USP5 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV99979188; called by muse, mutect2, varscan2
- VAV1 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.674); catalogued as COSV100409586; called by muse, mutect2, varscan2
- WAC | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100611239; called by muse, mutect2, varscan2
- ZFAND1 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV99605587; called by muse, mutect2, varscan2
- ZFAND2A | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100336008; called by muse, mutect2
- ZNF236 | c.4167+1G>A p.X1389_splice | Splice Site (SNP) | VAF 28/100 reads (28%) | catalogued as COSV53497430; called by muse, mutect2, varscan2
- ZNF419 | c.740T>C p.F247S | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1351613688, COSV99692761; called by muse, mutect2, varscan2
- ZNF701 | c.1035C>G p.F345L (on ENST00000301093; = p.F279L on NM_018260.3) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56525862, COSV99991063; called by muse, mutect2, varscan2
- VWC2L | c.*1del | Frame Shift Del (DEL) | VAF 43/144 reads (30%) | called by mutect2, pindel, varscan2
- AGPS | c.1926C>G p.V642= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV99931816; called by muse, mutect2, varscan2
- BTK | c.570A>T p.P190= | Silent (SNP) | VAF 51/79 reads (65%) | catalogued as COSV100438050; called by muse, mutect2, varscan2
- CAND2 | c.1923A>T p.P641= (on ENST00000456430 / NM_001162499.2; = p.P548= on NM_012298.3) | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV99930013; called by muse, mutect2, varscan2
- CCBE1 | c.699C>T p.I233= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV67949625; called by muse, mutect2, varscan2
- CCDC130 | c.1047G>C p.P349= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99237907, COSV99237934; called by muse, mutect2, varscan2
- CNOT7 | c.162C>T p.F54= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV100246697; called by muse, mutect2
- CREB3 | c.1089C>T p.V363= | Silent (SNP) | VAF 100/206 reads (49%) | catalogued as COSV59204180; called by muse, varscan2
- CYP27C1 | c.1047T>G p.A349= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV100080119; called by muse, mutect2, varscan2
- DEXI | c.168C>T p.L56= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs751650005, COSV100081204; called by muse, mutect2, varscan2
- DNAH2 | c.7545G>C p.T2515= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as COSV101209661; called by muse, mutect2, varscan2
- DOCK5 | c.3960G>C p.L1320= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99378365; called by muse, mutect2, varscan2
- DSCAM | c.5550G>A p.G1850= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as rs774865490, COSV68019907; called by muse, mutect2, varscan2
- DSG1 | c.1860C>T p.N620= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs548157114, COSV57132941; called by muse, mutect2, varscan2
- DZIP3 | c.132T>C p.D44= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as rs749896290, COSV100848137; called by muse, mutect2, varscan2
- EDEM1 | c.1335G>T p.L445= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV99849482; called by muse, mutect2, varscan2
- FGF10 | c.414G>A p.G138= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99241088; called by muse, mutect2
- GPD2 | c.318G>A p.G106= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as COSV100133772; called by muse, mutect2
- IMPG1 | c.423A>G p.G141= | Silent (SNP) | VAF 6/101 reads (6%) | catalogued as COSV100886785; called by muse, mutect2
- INSRR | c.321G>A p.T107= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs377729626; called by muse, mutect2, varscan2
- L3MBTL2 | c.1923C>T p.L641= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs776940912, COSV99346272; called by muse, varscan2
- LARP4 | c.1263G>A p.Q421= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as COSV99529799; called by muse, mutect2, varscan2
- MEF2C | c.483C>T p.V161= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV100426394; called by muse, mutect2, varscan2
- MYH9 | c.1983G>A p.L661= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99340068; called by muse, mutect2, varscan2
- OPTC | c.249C>T p.L83= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs907985750, COSV100921860, COSV65868410; called by muse, mutect2, varscan2
- OR5V1 | c.633C>T p.F211= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV65826333; called by muse, mutect2, varscan2
- PSORS1C1 | c.219C>A p.A73= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as COSV99456406; called by muse, mutect2, varscan2
- RSPO1 | c.27C>A p.A9= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100740720; called by muse, mutect2, varscan2
- SIGLEC14 | c.768G>A p.L256= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99708043; called by muse, mutect2, varscan2
- SLC18A1 | c.1435C>A p.R479= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs147512321, COSV99369035; called by muse, mutect2, varscan2
- SLC22A7 | c.921G>C p.R307= (on ENST00000372585 / NM_153320.2; = p.R305= on NM_006672.3) | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV99240661; called by muse, mutect2, varscan2
- SLC6A14 | c.1242C>T p.F414= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100903250; called by muse, mutect2, varscan2
- SPTBN5 | c.1263G>T p.L421= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100312462; called by muse, mutect2
- TMCC2 | c.954G>T p.L318= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100319602; called by muse, mutect2, varscan2
- UNC93A | c.855C>T p.C285= | Silent (SNP) | VAF 110/316 reads (35%) | catalogued as COSV100023762; called by muse, mutect2, varscan2
- USH2A | c.5448G>A p.V1816= | Silent (SNP) | VAF 10/270 reads (4%) | catalogued as COSV56350238, COSV56421534; called by muse, mutect2
- WDR91 | c.1878G>T p.G626= | Silent (SNP) | VAF 53/169 reads (31%) | catalogued as COSV100615882; called by muse, mutect2, varscan2
- ZNF517 | c.810C>T p.F270= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV100743827, COSV63464856; called by muse, mutect2, varscan2
- FAS | c.*112C>G | 3'UTR (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100570904, COSV58238455; called by muse, mutect2, varscan2
- H3C12 | c.*2C>T | 3'UTR (SNP) | VAF 21/67 reads (31%) | called by muse, varscan2
- KIR3DL2 | chr19:54847251 C>T | 5'Flank (SNP) | VAF 37/249 reads (15%) | called by muse, mutect2
- LINC02694 | n.269T>C | RNA (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100601963; called by muse, mutect2, varscan2
- PIGK | c.987-6978T>G | Intron (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- SSPOP | n.1444G>A | RNA (SNP) | VAF 5/10 reads (50%) | catalogued as rs764476658, COSV100022807; called by muse, varscan2
